TARGET case TARGET-30-PAMNLH — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7f61d2a1-703b-5e17-af68-16d2565f7556

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 837 days (2.3 years).

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 4.2 years (1,531 days); Year of diagnosis: 2003; Days to last follow up: 837 days (2.3 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 35; Percent tumor nuclei: 85.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: A3973.

Follow-up (3 entries)
- Days to follow up: 361 days; Progression or recurrence anatomic site: Bone marrow; Days to first event: 361 days; First event: Relapse.
- Days to follow up: 361 days; Progression or recurrence anatomic site: Bone, NOS.
- Days to follow up: 837 days (2.3 years); Year of follow up: 2005.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (3 samples)
- Samples TARGET-30-PAMNLH-01A, TARGET-30-PAMNLH-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAMNLH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 837
- Protocol: ANBL00B1, A3973
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.81
- Histology: Unfavorable
- Diagnostic Category: Ganglioneuroblastoma, nodular
- ICDO: C64.9
- ICDO Description: Kidney, NOS Renal, NOS Kidney parenchyma
- Site of Relapse: Bone; Bone Marrow
